Gene-level copy-number profile of tumor specimen C3N-01021-01 from CPTAC case C3N-01021, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 44.2 years (16,139 days).
Specimen C3N-01021-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 19471078-d1aa-42a1-a16c-1c224aa53595.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01021-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/324c3c84-8b51-49fb-b7ce-28139a694423

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 9,013; copy number 2: 42,218; copy number 3: 6,151; copy number 4: 246; copy number 5: 705; copy number 6: 63.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,345,661–149,556,361, 4 genes: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 768 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,689,256–149,321,732, 63 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–52,282,859, 705 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,011. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
